Gene-level copy-number profile of tumor specimen ALCH-B0CL-TTP1-A from ALCHEMIST case ALCH-B0CL, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 58.7 years (21,439 days).
Specimen ALCH-B0CL-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 03b6a04e-2192-4eec-adb7-e8b4f18f441c.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B0CL-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,709 have no estimate.
https://portal.gdc.cancer.gov/files/3ef5cca8-1afe-42f1-9db0-b96f466647e0

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 3; copy number 1: 5,467; copy number 2: 50,505; copy number 3: 2,074; copy number 4: 463; copy number 5: 304; copy number 6: 98.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 402 genes in 7 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:143,419,625–146,061,948, 98 genes, copy number 6 (broad region; genes not listed).
- chr1:149,923,317–151,953,985, 112 genes, copy number 5 (broad region; genes not listed).
- chr1:153,330,120–153,348,841, 1 gene, copy number 5 (within-gene range 4–5): PGLYRP4.
- chr1:153,357,854–155,187,272, 114 genes, copy number 5 (within-gene range 2–5) (broad region; genes not listed).
- chr1:194,188,967–194,719,236, 4 genes, copy number 5: EEF1A1P14, AL513348.1, RNU6-983P, AL353072.1.
- chr1:211,635,865–212,361,853, 25 genes, copy number 5: AL356310.1, LINC01693, NEK2, FDPSP8, AC096637.2, AC096637.1, LPGAT1, RN7SL344P, Y_RNA, LPGAT1-AS1, AC092814.2, INTS7, AC092814.1, DTL, RPL21P28, MIR3122, RN7SKP98, AL606468.1, LINC02608, PPP2R5A, AL360091.2, AL360091.3, RPL23AP18, SNORA16B, AL360091.1.
- chr5:9,621,377–11,904,446, 48 genes, copy number 5: AC026787.1, TAS2R1, LINC02112, RNA5SP177, AC091838.1, LINC02221, AC091905.2, AC091905.3, AC091905.1, AC091905.4, AC034229.1, AC034229.6, AC034229.5, AC034229.2, AC034229.3, AC034229.4, ATPSCKMT, AC012640.1, CCT5, AC012640.4, AC012640.3, CMBL, Y_RNA, Y_RNA, AC012640.5, AC012640.2, MARCHF6, ROPN1L-AS1, ROPN1L, MIR6131, LINC01513, RPL30P7, AC092336.1, LINC02212, LINC02213, AC112200.2, AC112200.1, ANKRD33B, ANKRD33B-AS1, AC106760.1, AC106760.2, AC012629.4, AC012629.3, DAP, AC012629.2, AC012629.1, CTNND2, RNU6-429P.

Autosomal genes at a single copy (total copy number 1): 2,625. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
